Somatic mutation profile of tumor specimen MMRF_1359_1_BM_CD138pos (aliquot MMRF_1359_1_BM_CD138pos_T1_KAS5U_L00666) from MMRF case MMRF_1359, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 54.8 years (20,033 days).
Specimen MMRF_1359_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e875420c-786d-4d62-a40f-baf654edaa00.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1359_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1359_1_PB_Whole_C2_KAS5U_L00679; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cc8b3f28-fe3d-46e3-ae21-69c1c74f36f0

The open-access MAF lists 77 somatic variants for this specimen: 26 protein-altering or splice-affecting, 9 silent, 42 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 30, Missense Mutation 22, Intron 10, Silent 9, Nonsense Mutation 3, 5'UTR 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 60/147 reads (41%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MAX | c.295+1G>A p.X99_splice | Splice Site (SNP) | VAF 63/67 reads (94%) | catalogued as rs786203385, CS115470, CS122951, COSV52417499, COSV52419813; ClinVar: pathogenic / risk factor; called by muse, mutect2, varscan2
- BAHCC1 | c.2468C>T p.P823L | Missense Mutation (SNP) | VAF 14/27 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1555653744; called by muse, mutect2, varscan2
- CRISP3 | c.614C>T p.A205V (on ENST00000371159 / NM_001368123.1; = p.A187V on NM_006061.4) | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as rs376851622, COSV53820126; called by muse, mutect2, varscan2
- DNAH5 | c.9472G>T p.E3158* | Nonsense Mutation (SNP) | VAF 38/65 reads (58%) | catalogued as COSV54242915; called by muse, mutect2, varscan2
- FAT1 | c.1090C>G p.P364A | Missense Mutation (SNP) | VAF 32/82 reads (39%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV71676051; called by muse, mutect2, varscan2
- IGLL5 | c.137A>T p.Q46L | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.057); catalogued as rs538001103, COSV73250994, COSV73251139; called by muse, varscan2
- IGLV3-1 | c.119C>G p.T40S | Missense Mutation (SNP) | VAF 22/54 reads (41%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.662); catalogued as rs371556422; called by muse, varscan2
- IGLV3-1 | c.131A>G p.D44G | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs774199094; called by muse, varscan2
- IGLV3-1 | c.292G>C p.A98P | Missense Mutation (SNP) | VAF 22/63 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.5); catalogued as rs534241034; called by muse, varscan2
- INSM2 | c.1520C>G p.P507R | Missense Mutation (SNP) | VAF 25/38 reads (66%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.467); catalogued as COSV51877700; called by muse, mutect2, varscan2
- KRT72 | c.629A>G p.D210G | Missense Mutation (SNP) | VAF 51/116 reads (44%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.979); catalogued as rs372551970; called by muse, mutect2, varscan2
- PCDHA3 | c.1436C>T p.A479V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as rs1554122256, COSV63543619; called by muse, mutect2
- TMC2 | c.1076C>A p.S359* | Nonsense Mutation (SNP) | VAF 10/24 reads (42%) | catalogued as COSV62650247; called by muse, mutect2
- TMEM63B | c.658G>A p.V220I | Missense Mutation (SNP) | VAF 27/65 reads (42%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.844); catalogued as rs748166685, COSV52476924; called by muse, mutect2, varscan2
- TMIGD2 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 45/90 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56667052; called by muse, mutect2, varscan2
- UBE3A | c.878A>C p.N293T | Missense Mutation (SNP) | VAF 26/41 reads (63%) | SIFT tolerated (0.4); PolyPhen benign (0.093); catalogued as rs587782908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGB | c.3994A>C p.K1332Q | Missense Mutation (SNP) | VAF 44/86 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); called by muse, varscan2
- AUP1 | c.106T>A p.F36I | Missense Mutation (SNP) | VAF 25/65 reads (38%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- B3GNT2 | c.759T>A p.H253Q | Missense Mutation (SNP) | VAF 36/64 reads (56%) | SIFT tolerated (0.29); PolyPhen benign (0.295); called by muse, mutect2, varscan2
- BNIP3L | c.28C>T p.P10S | Missense Mutation (SNP) | VAF 40/41 reads (98%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.857); called by muse, mutect2, varscan2
- CENPL | c.611T>G p.F204C | Missense Mutation (SNP) | VAF 48/132 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- CHST5 | c.502C>T p.Q168* | Nonsense Mutation (SNP) | VAF 55/192 reads (29%) | called by muse, mutect2, varscan2
- HTR3B | c.1067G>C p.R356T | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- POLE2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- SPRY2 | c.478C>G p.P160A | Missense Mutation (SNP) | VAF 18/40 reads (45%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2
- ACSBG1 | c.1887T>A p.T629= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- BHLHE40 | c.810G>A p.T270= | Silent (SNP) | VAF 57/103 reads (55%) | catalogued as rs771759156; called by muse, mutect2, varscan2
- ERICH3 | c.2856C>T p.D952= | Silent (SNP) | VAF 80/174 reads (46%) | called by muse, mutect2, varscan2
- EYA2 | c.1221G>A p.R407= | Silent (SNP) | VAF 36/69 reads (52%) | catalogued as rs267605971; called by muse, mutect2, varscan2
- IGLV3-1 | c.315C>T p.Y105= | Silent (SNP) | VAF 38/60 reads (63%) | catalogued as rs373828762; called by muse, varscan2
- KLK15 | c.474G>T p.R158= | Silent (SNP) | VAF 50/94 reads (53%) | called by muse, varscan2
- NUP210 | c.1851T>A p.S617= | Silent (SNP) | VAF 30/56 reads (54%) | called by muse, mutect2, varscan2
- PRDX6 | c.426G>A p.K142= | Silent (SNP) | VAF 116/183 reads (63%) | called by muse, mutect2, varscan2
- TLL1 | c.1179G>A p.T393= | Silent (SNP) | VAF 11/21 reads (52%) | catalogued as COSV50318919; called by muse, varscan2
- ACAN | c.2026+210G>A | Intron (SNP) | VAF 4/96 reads (4%) | called by muse, mutect2
- ACSS3 | c.*39C>T | 3'UTR (SNP) | VAF 47/95 reads (49%) | called by muse, mutect2, varscan2
- ALPK1 | c.*519T>A | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- AMER1 | c.*2116C>G | 3'UTR (SNP) | VAF 15/17 reads (88%) | called by muse, mutect2, varscan2
- ARAP2 | c.*1521A>G | 3'UTR (SNP) | VAF 26/65 reads (40%) | called by muse, mutect2, varscan2
- C2CD6 | c.1506+651A>C | Intron (SNP) | VAF 22/49 reads (45%) | called by muse, mutect2, varscan2
- CABP1 | c.655-4180G>A | Intron (SNP) | VAF 32/68 reads (47%) | called by muse, mutect2
- CCDC6 | c.*473T>G | 3'UTR (SNP) | VAF 15/31 reads (48%) | called by muse, mutect2, varscan2
- CD247 | c.*340C>T | 3'UTR (SNP) | VAF 11/100 reads (11%) | catalogued as rs374327474, COSV54824068; called by muse, mutect2, varscan2
- CFAP36 | c.537+10G>A | Intron (SNP) | VAF 11/29 reads (38%) | catalogued as rs374404021; called by muse, mutect2, varscan2
- CLMN | c.*180C>A | 3'UTR (SNP) | VAF 16/46 reads (35%) | called by muse, mutect2, varscan2
- CTBP1 | c.41-3382A>G | Intron (SNP) | VAF 7/13 reads (54%) | called by muse, mutect2, varscan2
- DENND2C | c.*481T>G | 3'UTR (SNP) | VAF 16/20 reads (80%) | called by muse, mutect2, varscan2
- EPHA7 | c.*3221G>A | 3'UTR (SNP) | VAF 7/23 reads (30%) | catalogued as rs1009636860; called by muse, mutect2, varscan2
- FAT4 | c.*366T>C | 3'UTR (SNP) | VAF 26/46 reads (57%) | called by muse, mutect2, varscan2
- FGD6 | c.4107+77T>C | Intron (SNP) | VAF 23/53 reads (43%) | called by muse, mutect2, varscan2
- GDF7 | c.*141C>T | 3'UTR (SNP) | VAF 17/34 reads (50%) | called by muse, mutect2, varscan2
- HSPA13 | c.*1120A>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- LPIN2 | c.590+29G>A | Intron (SNP) | VAF 4/10 reads (40%) | called by muse, varscan2
- LRRC58 | c.*1057T>C | 3'UTR (SNP) | VAF 17/30 reads (57%) | called by muse, mutect2, varscan2
- LTBR | c.473-15C>T | Intron (SNP) | VAF 37/39 reads (95%) | catalogued as rs752392667; called by muse, mutect2, varscan2
- MAFF | c.*105G>A | 3'UTR (SNP) | VAF 49/90 reads (54%) | called by muse, mutect2, varscan2
- NEIL3 | c.*71A>C | 3'UTR (SNP) | VAF 8/20 reads (40%) | called by muse, mutect2, varscan2
- NFE2L3 | c.*692C>T | 3'UTR (SNP) | VAF 30/69 reads (43%) | called by muse, mutect2, varscan2
- NIPAL2 | c.*707T>C | 3'UTR (SNP) | VAF 23/46 reads (50%) | called by muse, mutect2, varscan2
- NTRK3 | c.*15267A>C | 3'UTR (SNP) | VAF 11/28 reads (39%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | chr9:110172190 ins A | 3'Flank (INS) | VAF 19/50 reads (38%) | called by mutect2, pindel, varscan2
- PAX5 | c.*1105C>T | 3'UTR (SNP) | VAF 57/107 reads (53%) | called by muse, mutect2, varscan2
- POLR3K | c.*990T>G | 3'UTR (SNP) | VAF 27/59 reads (46%) | called by muse, mutect2, varscan2
- PPM1K | c.*474T>C | 3'UTR (SNP) | VAF 14/27 reads (52%) | called by muse, mutect2, varscan2
- PRR30 | c.-147G>A | 5'UTR (SNP) | VAF 3/35 reads (9%) | called by muse, mutect2
- PSD3 | c.*1137T>G | 3'UTR (SNP) | VAF 18/19 reads (95%) | called by muse, mutect2, varscan2
- RNF13 | c.*588del | 3'UTR (DEL) | VAF 19/122 reads (16%) | catalogued as rs1315957518; called by mutect2, varscan2
- SCN1A | c.*189A>G | 3'UTR (SNP) | VAF 8/41 reads (20%) | called by muse, mutect2, varscan2
- SHISA9 | c.*291C>A | 3'UTR (SNP) | VAF 19/44 reads (43%) | catalogued as rs1404620553; called by muse, mutect2, varscan2
- SLC6A15 | c.*1905T>A | 3'UTR (SNP) | VAF 27/60 reads (45%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+49282C>T | Intron (SNP) | VAF 17/29 reads (59%) | catalogued as rs936817089; called by muse, mutect2, varscan2
- TMEM108 | c.1451-2005C>T | Intron (SNP) | VAF 24/55 reads (44%) | called by muse, mutect2, varscan2
- TPRG1 | c.*3500T>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | called by muse, mutect2, varscan2
- UNC93A | c.*157del | 3'UTR (DEL) | VAF 22/88 reads (25%) | catalogued as rs67843022; called by mutect2, varscan2
- VSIR | c.*1963G>C | 3'UTR (SNP) | VAF 34/89 reads (38%) | called by muse, mutect2, varscan2
- ZNF563 | c.*1047G>A | 3'UTR (SNP) | VAF 10/26 reads (38%) | catalogued as rs886499762; called by muse, mutect2, varscan2
